Gene-level copy-number profile of tumor specimen C3L-06418-01 from CPTAC case C3L-06418, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.4 years (24,990 days).
Specimen C3L-06418-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2759038c-88bf-43da-8f58-f7f3bfc92ddd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06418-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/7cba472b-2815-45a7-a1a0-d07e32a66015

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 731; copy number 1: 14,381; copy number 2: 34,854; copy number 3: 7,666; copy number 4: 1,277; copy number 7: 5.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,560,024–116,667,755, 2 genes (within-gene range 0–1): MIR548AC, IGSF3.
- chr1:248,573,801–248,635,091, 5 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr3:42,013,802–42,410,610, 9 genes: TRAK1, AC093414.1, TPMTP2, RNU4-78P, CCK, AC018358.1, SALL4P6, EIF4BP4, LYZL4.
- chr9:20,331,446–25,089,151, 82 genes (broad region; genes not listed).
- chr9:98,807,670–99,070,792, 5 genes: GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–2): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:64,621,560–64,765,535, 5 genes, copy number 7: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.

Autosomal genes at a single copy (total copy number 1): 12,640. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
